Somatic mutation profile of tumor specimen 93e30fd5-e57e-4503-a175-863c7d (aliquot CPT0052940010) from CPTAC case 11LU016, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 62.2 years (22,733 days).
Specimen 93e30fd5-e57e-4503-a175-863c7d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2d4e73f-1809-4f0e-ab08-116c0026c512.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 953d4247-a33a-4caa-a0de-2f19cd (Blood Derived Normal), aliquot CPT0037120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71eca4a5-ca99-491d-9c3a-e0c6ec41b044

The open-access MAF lists 676 somatic variants for this specimen: 475 protein-altering or splice-affecting, 125 silent, 76 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 403, Silent 125, Intron 37, Nonsense Mutation 24, Frame Shift Del 19, RNA 14, Splice Site 13, 3'UTR 13, Splice Region 12, 5'UTR 6, 3'Flank 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2155G>T p.G719C | Missense Mutation (SNP) | VAF 160/474 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28929495, COSV51766606, COSV51767289; ClinVar: pathogenic / drug response / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2303G>T p.S768I | Missense Mutation (SNP) | VAF 103/344 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913465, COSV51768106, COSV51821681, COSV51833841; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.764_765insTAT p.I255dup | In Frame Ins (INS) | VAF 49/240 reads (20%) | hotspot (GDC flag); catalogued as COSV99037193; called by pindel, varscan2
- ABHD11 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.106); catalogued as rs782058055; called by muse, mutect2, varscan2
- ACSM1 | c.1197G>T p.Q399H | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs868418504; called by muse, mutect2, varscan2
- ACSM1 | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 78/315 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99533219; called by muse, mutect2, varscan2
- ADAMTS12 | c.4119G>C p.W1373C | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61263279; called by muse, mutect2, varscan2
- APOB | c.9407G>T p.R3136L | Missense Mutation (SNP) | VAF 38/292 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV51926551; called by muse, mutect2, varscan2
- ARHGEF16 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs536938385, COSV65682005; called by muse, mutect2, varscan2
- AXDND1 | c.2714G>T p.W905L | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.886); catalogued as COSV62643050; called by muse, mutect2
- BBX | c.1980G>T p.W660C | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as COSV100361597; called by muse, mutect2
- CA10 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 29/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53353595; called by muse, mutect2, varscan2
- CACNA1I | c.1286C>A p.A429D | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1216366631; called by muse, mutect2, varscan2
- CACNA2D3 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV55581157; called by muse, mutect2
- CHD5 | c.4313G>T p.R1438L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99313659; called by muse, mutect2, varscan2
- CLCA1 | c.1311G>T p.L437F | Missense Mutation (SNP) | VAF 11/174 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.766); catalogued as COSV52332254, COSV99322087; called by muse, mutect2
- COG5 | c.306G>T p.M102I | Missense Mutation (SNP) | VAF 91/570 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.714); catalogued as COSV99771511; called by muse, mutect2, varscan2
- COL11A1 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 35/258 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62196120; called by muse, mutect2, varscan2
- CSMD3 | c.6648C>A p.Y2216* (on ENST00000297405 / NM_001363185.1; = p.Y2112* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 35/208 reads (17%) | catalogued as rs1264427816, COSV52202231; called by muse, mutect2, varscan2
- CTAGE1 | c.2222C>A p.P741Q | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1283931790; called by muse, varscan2
- DNM2 | c.992+3A>G | Splice Region (SNP) | VAF 18/495 reads (4%) | catalogued as rs1053695479; called by muse, mutect2
- DTNA | c.1766C>A p.T589K | Missense Mutation (SNP) | VAF 113/383 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV52008314; called by muse, mutect2, varscan2
- EFCAB6 | c.1249A>T p.T417S | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV53069084; called by muse, mutect2, varscan2
- EGF | c.1624G>T p.D542Y | Missense Mutation (SNP) | VAF 43/412 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99490474; called by muse, mutect2, varscan2
- EPHA5 | c.2392C>T p.H798Y | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99901833; called by muse, mutect2, varscan2
- ERBB4 | c.2750G>T p.G917V | Missense Mutation (SNP) | VAF 51/312 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61481940; called by muse, mutect2, varscan2
- EXOC6B | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs749620876, COSV55573318; called by muse, mutect2, varscan2
- FAM171B | c.1376A>T p.D459V | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1559094702; called by muse, mutect2, varscan2
- FAT1 | c.8470G>T p.G2824W | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV71674308; called by muse, mutect2, varscan2
- FAT3 | c.7661C>T p.T2554I | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1165066379; called by muse, mutect2, varscan2
- FCRL1 | c.1286T>G p.M429R | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV100839766; called by muse, mutect2, varscan2
- FGF14 | c.154C>A p.R52S | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV65935189, COSV65937383; called by muse, mutect2, varscan2
- FGG | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.036); catalogued as rs187841130; called by muse, mutect2
- FRAS1 | c.11236G>A p.E3746K | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767238519; called by muse, mutect2
- FSCB | c.535G>T p.E179* | Nonsense Mutation (SNP) | VAF 26/158 reads (16%) | catalogued as COSV61218110; called by muse, mutect2, varscan2
- FTMT | c.176C>A p.T59N | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs762527865; called by muse, mutect2, varscan2
- GCDH | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 58/295 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55820120; called by muse, mutect2, varscan2
- GOLGA4 | c.1306G>T p.E436* | Nonsense Mutation (SNP) | VAF 43/222 reads (19%) | catalogued as COSV100729216, COSV62711002; called by muse, mutect2, varscan2
- HBD | c.114G>C p.W38C | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53082068; called by muse, mutect2, varscan2
- HELZ2 | c.2466G>C p.W822C (on ENST00000467148 / NM_001037335.2; = p.W253C on NM_033405.3) | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915449; called by muse, mutect2
- HMX3 | c.605C>A p.A202E | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.116); catalogued as rs1319294328, COSV63501965; called by muse, mutect2, varscan2
- HOXA3 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV100415341; called by muse, mutect2, varscan2
- HRNR | c.2881G>A p.G961S | Missense Mutation (SNP) | VAF 190/747 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.601); catalogued as rs1303172060, COSV100913817; called by muse, mutect2, varscan2
- HRNR | c.2093C>A p.S698Y | Missense Mutation (SNP) | VAF 115/523 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV64260977; called by muse, mutect2, varscan2
- HTR2C | c.162del p.W55Gfs*9 | Frame Shift Del (DEL) | VAF 73/178 reads (41%) | catalogued as COSV99350452; called by mutect2, pindel, varscan2
- IGHV3-53 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.286); catalogued as rs782540340; called by muse, mutect2
- IGSF1 | c.2180G>T p.G727V | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.898); catalogued as rs780672123; called by muse, mutect2, varscan2
- IKZF1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 91/270 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100498199, COSV100498439; called by muse, mutect2, varscan2
- IRX6 | c.1010C>A p.P337H | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.401); catalogued as COSV51861174, COSV99306704; called by muse, mutect2
- ISL2 | c.728G>A p.R243H | Missense Mutation (SNP) | VAF 10/187 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99320781; called by muse, mutect2
- ITGAV | c.2773G>C p.A925P | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs1183190099; called by muse, mutect2, varscan2
- JMJD6 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1177861863; called by muse, mutect2, varscan2
- JPH3 | c.2009C>A p.S670Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs1202619928; called by muse, mutect2, varscan2
- KCNC2 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 71/259 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100129229; called by muse, mutect2, varscan2
- KLHL29 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1042988239; called by muse, mutect2, varscan2
- KLK1 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs1253394005; called by muse, mutect2, varscan2
- LCT | c.3518G>T p.G1173V | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV51550308; called by muse, mutect2, varscan2
- LRATD1 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 47/249 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV54473660; called by muse, mutect2, varscan2
- LRRC24 | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 29/219 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1272725642, COSV52881961; called by muse, mutect2, varscan2
- MAGEA4 | c.-65-4G>T | Splice Region (SNP) | VAF 48/151 reads (32%) | catalogued as rs760092762, COSV52343215; called by muse, mutect2, varscan2
- MC5R | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.386); catalogued as COSV61253907; called by muse, mutect2, varscan2
- MCHR2 | c.796C>A p.P266T | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56002178; called by muse, mutect2
- MCTP2 | c.1788+1G>T p.X596_splice | Splice Site (SNP) | VAF 28/122 reads (23%) | catalogued as rs200626556, COSV59143183; called by mutect2, varscan2
- MDGA2 | c.2576G>T p.R859L (on ENST00000399232 / NM_001113498.2; = p.R561L on NM_182830.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as COSV62081945; called by muse, mutect2, varscan2
- MKLN1 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.001); catalogued as COSV61762385; called by muse, mutect2, varscan2
- MOG | c.481del p.V161Cfs*22 | Frame Shift Del (DEL) | VAF 46/316 reads (15%) | catalogued as COSV65321766; called by mutect2, pindel, varscan2
- MUC16 | c.39856C>A p.Q13286K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.34); catalogued as rs942983341; called by muse, mutect2, varscan2
- MXRA5 | c.5389G>T p.G1797* | Nonsense Mutation (SNP) | VAF 18/119 reads (15%) | catalogued as COSV54253876; called by muse, mutect2, varscan2
- MYH1 | c.3845C>T p.A1282V | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs746118240, COSV56846440; called by muse, varscan2
- MYH6 | c.1960C>A p.R654= | Splice Region (SNP) | VAF 83/454 reads (18%) | catalogued as rs369938365, COSV62454248; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- MYO7A | c.4465G>T p.V1489F | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.997); catalogued as COSV68683839; called by muse, mutect2, varscan2
- MYOD1 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.109); catalogued as COSV51453885; called by muse, mutect2
- NCAPD3 | c.4253-7T>C | Splice Region (SNP) | VAF 34/294 reads (12%) | catalogued as rs763889522; called by muse, mutect2, varscan2
- NCKAP1 | c.271G>T p.A91S | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs774900528; called by muse, mutect2, varscan2
- NPAS3 | c.1591A>T p.S531C (on ENST00000356141 / NM_001164749.2; = p.S499C on NM_022123.3) | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV60844752; called by muse, mutect2, varscan2
- NPY2R | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 25/299 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61529613; called by muse, mutect2
- NTRK2 | c.584-1G>T p.X195_splice | Splice Site (SNP) | VAF 84/382 reads (22%) | catalogued as COSV52870717; called by muse, mutect2, varscan2
- NUP155 | c.572A>G p.N191S (on ENST00000231498 / NM_153485.3; = p.N132S on NM_004298.4) | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.675); catalogued as rs1026952521; called by muse, mutect2, varscan2
- OR2AK2 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV63550170; called by mutect2, varscan2
- OR4C11 | c.751C>G p.P251A | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV100155592, COSV56353774; called by muse, mutect2, varscan2
- OR5T2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV57589923, COSV57590240; called by muse, mutect2, varscan2
- OVCH1 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 70/341 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV58962190; called by muse, mutect2, varscan2
- PAPPA2 | c.372G>T p.E124D | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs757885352, COSV62783020; called by muse, mutect2, varscan2
- PCDH11X | c.1676G>T p.S559I | Missense Mutation (SNP) | VAF 23/335 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV53488594; called by muse, mutect2
- PCDH15 | c.4084A>G p.S1362G | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs1343337397; called by muse, mutect2
- PCLO | c.12505C>A p.L4169I | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.909); catalogued as COSV61647346; called by muse, mutect2
- PCMT1 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs778241850; called by muse, mutect2
- PEG3 | c.498C>A p.D166E | Missense Mutation (SNP) | VAF 75/219 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs757890759, COSV99687933; called by muse, mutect2, varscan2
- PGD | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199971575; called by muse, mutect2, varscan2
- PHYHIPL | c.540G>A p.M180I | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV65849625; called by muse, mutect2
- PIWIL1 | c.1316G>C p.R439P | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV55350319; called by muse, mutect2, varscan2
- PKD1 | c.12292G>T p.A4098S (on ENST00000262304 / NM_001009944.3; = p.A4097S on NM_000296.4) | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as COSV51916501; called by muse, mutect2, varscan2
- POM121L12 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 18/466 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.249); catalogued as rs1192466338, COSV68692621, COSV68693468; called by muse, mutect2
- PRRT1 | c.921A>C p.*307Yext*107 | Nonstop Mutation (SNP) | VAF 22/190 reads (12%) | catalogued as COSV52999660; called by muse, mutect2, varscan2
- PYCR3 | c.523G>T p.G175C | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1419397430; called by muse, mutect2, varscan2
- PZP | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs1008372137; called by muse, mutect2
- RAB11FIP1 | c.2851A>G p.I951V | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756794766; called by muse, mutect2, varscan2
- RB1 | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD040609; called by muse, mutect2, varscan2
- RHBDL3 | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.831); catalogued as COSV52185868; called by muse, mutect2, varscan2
- RNF217 | c.1615G>T p.G539C | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1215990811; called by muse, mutect2, varscan2
- RPL10 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 35/312 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.468); catalogued as COSV50010118; called by muse, mutect2, varscan2
- SARDH | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 33/323 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs775825403, COSV100898452; called by muse, mutect2, varscan2
- SCN11A | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 28/352 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV100181967; called by muse, mutect2
- SDK1 | c.4370G>T p.R1457M | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV101269367; called by muse, varscan2
- SFMBT2 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62808284; called by muse, mutect2, varscan2
- SLC25A13 | c.527G>T p.G176V | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM139589; called by muse, mutect2
- SLC5A12 | c.1744del p.A582Lfs*43 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as rs1320413363, COSV68448540; called by mutect2, pindel
- SMAD6 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748124400, COSV56596273; called by muse, mutect2, varscan2
- SP6 | c.550G>T p.G184W | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as rs867558995, COSV100646947; called by muse, mutect2, varscan2
- SPATA31D1 | c.4643G>A p.S1548N | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.451); catalogued as COSV100783120; called by muse, mutect2, varscan2
- SPRY3 | c.269A>G p.H90R | Missense Mutation (SNP) | VAF 175/459 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs755672247; called by muse, mutect2, varscan2
- STAB2 | c.4508G>C p.G1503A | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs560420677; called by muse, mutect2, varscan2
- STARD9 | c.4504G>A p.A1502T | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as rs1416444119; called by muse, mutect2, varscan2
- SUCLG1 | c.901G>A p.G301R | Missense Mutation (SNP) | VAF 87/394 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1427132683; called by muse, mutect2, varscan2
- SYNE2 | c.14677G>T p.A4893S | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as rs772278774; called by muse, mutect2, varscan2
- TAF1L | c.3390G>C p.K1130N | Missense Mutation (SNP) | VAF 24/280 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.463); catalogued as COSV99645782; called by muse, mutect2
- TBC1D32 | c.2668T>G p.L890V | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV51541575; called by muse, mutect2
- TCF21 | c.166C>A p.L56M | Missense Mutation (SNP) | VAF 70/362 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as COSV52818398; called by muse, mutect2, varscan2
- TDRD15 | c.947del p.P316Qfs*4 | Frame Shift Del (DEL) | VAF 15/83 reads (18%) | catalogued as rs1558298819; called by mutect2, pindel, varscan2
- TEX13C | c.2110C>G p.P704A | Missense Mutation (SNP) | VAF 198/430 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV66745103; called by muse, varscan2
- TJAP1 | c.287G>T p.R96L | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV52499614; called by muse, varscan2
- TMSB4Y | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV53027438; called by muse, mutect2, varscan2
- TOPORS | c.2248G>C p.A750P | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.361); catalogued as rs1563983382; called by muse, mutect2
- TP73 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.386); catalogued as COSV60701106; called by muse, mutect2, varscan2
- TRBV6-1 | c.329G>A p.C110Y | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1252923676; called by muse, mutect2
- TTN | c.82362T>G p.I27454M (on ENST00000591111; = p.I20030M on NM_003319.4) | Missense Mutation (SNP) | VAF 61/275 reads (22%) | PolyPhen benign (0.005); catalogued as COSV60199609; called by muse, mutect2, varscan2
- TUBA3E | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 51/397 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.984); catalogued as rs199933182, COSV99919767; called by muse, mutect2, varscan2
- URB1 | c.6520A>C p.N2174H | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs1339027538; called by muse, mutect2, varscan2
- VN1R4 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 36/109 reads (33%) | catalogued as COSV100237395; called by muse, mutect2, varscan2
- ZNF16 | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 33/249 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52763345; called by muse, mutect2, varscan2
- ZNF208 | c.3578G>T p.G1193V | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs754259797; called by muse, mutect2, varscan2
- ZNF672 | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs928516606, COSV60638690; called by muse, mutect2
- ZPBP | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 31/484 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.216); catalogued as COSV50422796; called by muse, mutect2
- ZSCAN4 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV59000592; called by muse, varscan2
- ABCA10 | c.4395A>T p.E1465D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- ABCA12 | c.1360C>A p.Q454K (on ENST00000272895 / NM_173076.3; = p.Q136K on NM_015657.3) | Missense Mutation (SNP) | VAF 72/467 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.019); called by muse, varscan2
- ABCC8 | c.982G>T p.G328W | Missense Mutation (SNP) | VAF 45/397 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2
- ADAMTS12 | c.1096C>G p.L366V | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- ADAMTS18 | c.93G>T p.A31= | Splice Region (SNP) | VAF 30/164 reads (18%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.3386del p.P1129Qfs*2 | Frame Shift Del (DEL) | VAF 45/205 reads (22%) | called by mutect2, pindel, varscan2
- ADCY1 | c.1807C>A p.Q603K | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- ADCY1 | c.1808A>G p.Q603R | Missense Mutation (SNP) | VAF 24/268 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- ADCY2 | c.2111C>A p.S704* | Nonsense Mutation (SNP) | VAF 23/126 reads (18%) | called by muse, mutect2, varscan2
- ADCY6 | c.3377T>G p.I1126S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADCY8 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADD1 | c.1476G>T p.L492F | Missense Mutation (SNP) | VAF 26/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- ADGRB1 | c.1855G>T p.D619Y | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL3 | c.1060del p.V354Sfs*5 (on ENST00000506720 / NM_001322402.2; = p.V286Sfs*5 on NM_015236.6) | Frame Shift Del (DEL) | VAF 32/282 reads (11%) | called by mutect2, pindel, varscan2
- ADGRL4 | c.1749T>C p.L583= | Splice Region (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- AHNAK2 | c.6845C>A p.P2282H | Missense Mutation (SNP) | VAF 143/649 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- AKR1C4 | c.309del p.K105Nfs*33 | Frame Shift Del (DEL) | VAF 16/162 reads (10%) | called by mutect2, pindel
- ALPI | c.414C>A p.N138K | Missense Mutation (SNP) | VAF 48/357 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- ALPI | c.415C>A p.Q139K | Missense Mutation (SNP) | VAF 48/345 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.035); called by mutect2, varscan2
- ALS2CL | c.846G>A p.G282= | Splice Region (SNP) | VAF 32/245 reads (13%) | called by muse, mutect2, varscan2
- ANAPC1 | c.3995G>T p.G1332V | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ANAPC2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ANK2 | c.10607G>A p.R3536K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2
- ANKRD30A | c.3145A>G p.R1049G (on ENST00000611781; = p.R993G on NM_052997.2) | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.259); called by muse, mutect2
- ANKRD42 | c.483C>G p.D161E | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ANO7 | c.529G>T p.A177S (on ENST00000274979; = p.A123S on NM_001370694.2) | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ARC | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); called by muse, mutect2
- ARHGAP28 | c.1617G>C p.M539I (on ENST00000383472 / NM_001366230.1; = p.M380I on NM_001010000.3) | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.114); called by muse, mutect2
- ARHGAP45 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF3 | c.1321_1328del p.L441Yfs*19 | Frame Shift Del (DEL) | VAF 16/180 reads (9%) | called by mutect2, pindel
- ARL6IP1 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASAP1 | c.1516-2A>T p.X506_splice | Splice Site (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- ATP11B | c.2159G>T p.C720F | Missense Mutation (SNP) | VAF 62/313 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BAIAP3 | c.149T>A p.V50E | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BEGAIN | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- BNC1 | c.881C>A p.S294Y | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- BNC2 | c.909C>A p.N303K | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.115); called by muse, mutect2
- BRPF3 | c.2764G>T p.G922C | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- BRWD1 | c.3856T>C p.L1286= | Splice Region (SNP) | VAF 9/130 reads (7%) | called by muse, mutect2
- C15orf40 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C16orf82 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 66/409 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- C19orf38 | c.263G>T p.C88F | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1orf68 | c.663T>A p.C221* | Nonsense Mutation (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- CAND1 | c.148G>C p.V50L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CASP9 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CASS4 | c.2226C>A p.S742R | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- CCDC178 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCR10 | c.323T>A p.L108Q | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- CD200R1L | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- CEP170 | c.1150G>T p.A384S | Missense Mutation (SNP) | VAF 47/137 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CEP250 | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CFAP54 | c.8766G>T p.M2922I | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- CFAP74 | c.2079G>T p.E693D | Missense Mutation (SNP) | VAF 20/236 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.149); called by muse, mutect2
- CHIC1 | c.439T>C p.C147R | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CHRNA6 | c.896T>A p.V299E | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- CIDEB | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 40/190 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCA4 | c.2425C>T p.Q809* | Nonsense Mutation (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- CLEC17A | c.363C>A p.G121= | Splice Region (SNP) | VAF 17/400 reads (4%) | called by muse, mutect2
- CNTNAP4 | c.2344C>T p.P782S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL15A1 | c.1036G>C p.G346R | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- COL22A1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- COL24A1 | c.4944G>T p.Q1648H | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- CPS1 | c.61A>C p.T21P | Missense Mutation (SNP) | VAF 15/365 reads (4%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.015); called by muse, mutect2
- CSMD1 | c.7843A>T p.R2615W (on ENST00000520002; = p.R2614W on NM_033225.6) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, varscan2
- CSMD3 | c.3169A>T p.S1057C (on ENST00000297405 / NM_001363185.1; = p.S953C on NM_052900.3) | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CTAGE6 | c.654A>T p.Q218H | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by mutect2, varscan2
- CTPS1 | c.664C>G p.L222V | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DCTN6 | c.208A>G p.I70V | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX56 | c.961G>T p.G321W | Missense Mutation (SNP) | VAF 63/214 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- DENND2C | c.2642G>T p.R881L (on ENST00000393274 / NM_001256404.2; = p.R824L on NM_198459.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- DENND5B | c.3562T>A p.Y1188N | Missense Mutation (SNP) | VAF 44/208 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DGCR2 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- DLL1 | c.1848C>A p.N616K | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH5 | c.11551T>C p.F3851L | Missense Mutation (SNP) | VAF 129/601 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DNAI3 | c.1440A>T p.K480N | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- DNAJC10 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); called by muse, mutect2
- DOCK1 | c.3884C>T p.A1295V | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- DOCK6 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- DPYSL2 | c.365A>T p.Q122L | Missense Mutation (SNP) | VAF 14/221 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); called by muse, mutect2
- DSCAM | c.1954A>G p.S652G | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2
- EBF3 | c.770del p.Y257Ffs*27 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- EEF1A1 | c.144+2T>C p.X48_splice | Splice Site (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- EHD1 | c.623A>G p.K208R | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT tolerated (0.86); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ENOSF1 | c.736G>T p.G246W (on ENST00000340116 / NM_001354066.2; = p.G198W on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/233 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EP400 | c.6265G>T p.V2089L | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERCC4 | c.2549A>T p.D850V | Missense Mutation (SNP) | VAF 19/284 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- F5 | c.2213C>G p.S738* | Nonsense Mutation (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2
- FAM135B | c.4142C>A p.A1381D | Missense Mutation (SNP) | VAF 43/355 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM149A | c.2173G>T p.D725Y (on ENST00000356371 / NM_001367768.2; = p.D434Y on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FAM171A2 | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- FAM197Y1 | n.356+1G>T | Splice Site (SNP) | VAF 71/169 reads (42%) | called by muse, mutect2, varscan2
- FAT3 | c.11375_11376del p.C3792Sfs*22 | Frame Shift Del (DEL) | VAF 62/274 reads (23%) | called by pindel, varscan2
- FBN3 | c.6910G>T p.V2304L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FCGBP | c.5438G>T p.G1813V | Missense Mutation (SNP) | VAF 240/1033 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FETUB | c.938A>T p.K313I | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- FMNL3 | c.1433T>C p.L478P | Missense Mutation (SNP) | VAF 43/296 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FMO1 | c.553A>T p.K185* | Nonsense Mutation (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- FOXL1 | c.524G>T p.G175V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FRS2 | c.857G>T p.W286L | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FRY | c.2339A>T p.D780V | Missense Mutation (SNP) | VAF 60/333 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FSTL5 | c.1301C>A p.A434D | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- FZD5 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 43/255 reads (17%) | called by muse, mutect2, varscan2
- FZD5 | c.603G>T p.K201N | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GABRA5 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GALR1 | c.870C>A p.C290* | Nonsense Mutation (SNP) | VAF 64/336 reads (19%) | called by muse, mutect2, varscan2
- GEMIN2 | c.818G>C p.R273P | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GFOD2 | c.398T>A p.M133K | Missense Mutation (SNP) | VAF 66/301 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- GJB6 | c.86T>C p.F29S | Missense Mutation (SNP) | VAF 86/369 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GOLGB1 | c.2839G>T p.E947* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- GPR143 | c.180del p.A61Rfs*26 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- GPR143 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.265); called by mutect2, varscan2
- GPR27 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GPR31 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- GRB14 | c.679-1G>T p.X227_splice | Splice Site (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- GRK1 | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- GSC | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- GTF2I | c.2597G>C p.R866T (on ENST00000573035 / NM_032999.4; = p.R825T on NM_001518.5) | Missense Mutation (SNP) | VAF 26/561 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- HAUS6 | c.2135A>T p.E712V | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- HEG1 | c.1258G>T p.G420* | Nonsense Mutation (SNP) | VAF 22/120 reads (18%) | called by muse, varscan2
- HELB | c.1430G>A p.G477D | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HELZ | c.5785G>T p.G1929W | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERPUD2 | c.1025G>T p.G342V | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HIVEP2 | c.5407G>T p.E1803* | Nonsense Mutation (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- HNRNPUL1 | c.662A>T p.H221L | Missense Mutation (SNP) | VAF 67/258 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- HOXA3 | c.1277G>A p.G426D | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HOXB13 | c.298T>A p.C100S | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- HRH2 | c.747del p.Y250Tfs*10 | Frame Shift Del (DEL) | VAF 34/364 reads (9%) | called by mutect2, pindel
- HSD11B2 | c.839A>T p.K280M | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); called by muse, mutect2
- HTR5A | c.425C>A p.S142Y | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HTR6 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- HTR7 | c.1361T>A p.L454Q | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.068); called by muse, varscan2
- HTR7 | c.227A>G p.Y76C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- HTRA3 | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 82/304 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- HYAL4 | c.279C>A p.N93K | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- IGHV2-26 | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- IL21R | c.1209C>A p.D403E | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- IL33 | c.470-2A>T p.X157_splice | Splice Site (SNP) | VAF 21/133 reads (16%) | called by muse, mutect2, varscan2
- INF2 | c.2917A>T p.I973F | Missense Mutation (SNP) | VAF 77/505 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INMT | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- IQCE | c.1396A>G p.M466V | Missense Mutation (SNP) | VAF 25/289 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- IRF8 | c.887G>T p.R296L | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- IRX3 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGB8 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT tolerated (0.92); PolyPhen benign (0.104); called by muse, varscan2
- JAML | c.377T>A p.V126E (on ENST00000356289 / NM_001098526.2; = p.V116E on NM_153206.3) | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JPH3 | c.1736C>A p.P579H | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.125); called by muse, mutect2
- KCNH7 | c.2339C>G p.T780S | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- KCNH7 | c.579T>A p.D193E | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- KDM4B | c.2036G>C p.R679P | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- KIF6 | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIN | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.563); called by muse, mutect2
- KNDC1 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KRT12 | c.554A>T p.D185V | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- KRTAP9-7 | c.448T>G p.C150G | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- LCT | c.1369T>A p.W457R | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LEXM | c.109G>C p.D37H | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LIPK | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- LRBA | c.4903G>T p.D1635Y | Missense Mutation (SNP) | VAF 32/258 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC24 | c.1288C>A p.R430S | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- LRRC36 | c.1885G>A p.G629S | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC4C | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRIQ3 | c.1099A>C p.N367H | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRK2 | c.4975G>T p.A1659S | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- MACF1 | c.16731G>C p.W5577C (on ENST00000372915; = p.W3619C on NM_012090.5) | Missense Mutation (SNP) | VAF 22/297 reads (7%) | called by muse, mutect2
- MAGEB2 | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- MAGEB2 | c.170G>T p.G57V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- MAP3K4 | c.624A>T p.R208S | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2
- MAP4K1 | c.568G>T p.G190* | Nonsense Mutation (SNP) | VAF 44/163 reads (27%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 29/405 reads (7%) | SIFT tolerated (1); PolyPhen probably damaging (1); called by muse, mutect2
- MARK1 | c.1524A>T p.E508D | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MBTPS2 | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 97/217 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- MCF2 | c.2449+1G>T p.X817_splice | Splice Site (SNP) | VAF 45/78 reads (58%) | called by muse, mutect2, varscan2
- MEOX2 | c.70dup p.Q24Pfs*11 | Frame Shift Ins (INS) | VAF 23/270 reads (9%) | called by mutect2, pindel
- MEX3B | c.511G>T p.V171L | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MGAM | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MICAL3 | c.4533G>T p.K1511N | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MMD2 | c.402C>A p.H134Q | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MNDA | c.871C>A p.Q291K | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- MSL1 | c.1616A>G p.Y539C (on ENST00000398532 / NM_001365919.1; = p.Y276C on NM_001012241.2) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MUC1 | c.104A>T p.K35M | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2
- MYB | c.894A>T p.L298F | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2
- MYCBP2 | c.6872A>T p.Q2291L (on ENST00000357337; = p.Q2329L on NM_015057.5) | Missense Mutation (SNP) | VAF 38/276 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MYLK3 | c.2277G>T p.M759I | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- MYLK3 | c.1677C>A p.N559K | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- MYRIP | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- NCAPD3 | c.3907C>T p.Q1303* | Nonsense Mutation (SNP) | VAF 21/239 reads (9%) | called by muse, mutect2
- NEB | c.7528A>C p.T2510P | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEK10 | c.3488G>T p.W1163L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NIBAN3 | c.2084C>T p.P695L | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- NKAP | c.950A>T p.E317V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NLGN1 | c.1234G>C p.D412H | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- NOS1 | c.3089T>C p.L1030P | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOTCH2 | c.1046_1062del p.P349Rfs*23 | Frame Shift Del (DEL) | VAF 88/445 reads (20%) | called by mutect2, pindel, varscan2
- NOTUM | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NPBWR2 | c.312G>T p.E104D | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT tolerated (0.81); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NPFFR2 | c.1077G>T p.K359N | Missense Mutation (SNP) | VAF 72/236 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRAP | c.4390G>T p.D1464Y (on ENST00000359988 / NM_001322945.2; = p.D1429Y on NM_006175.4) | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- NRXN1 | c.4216G>T p.G1406W | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NTRK3 | c.532G>A p.G178R | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- NTSR2 | c.872G>T p.S291I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2
- NYNRIN | c.2145G>T p.K715N | Missense Mutation (SNP) | VAF 15/210 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- OR10H3 | c.581C>A p.T194K | Missense Mutation (SNP) | VAF 91/488 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- OR10R2 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- OR1C1 | c.554T>C p.L185P | Missense Mutation (SNP) | VAF 50/262 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- OR4C12 | c.334C>A p.L112M | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OR4C5 | c.259T>A p.F87I | Missense Mutation (SNP) | VAF 26/223 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR51E1 | c.6G>T p.M2I | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, varscan2
- OR52J3 | c.609T>G p.F203L | Missense Mutation (SNP) | VAF 42/195 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- OR6B1 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR7D2 | c.777C>G p.H259Q | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.317); called by muse, mutect2
- OR8J3 | c.531T>A p.F177L | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2
- OSBPL5 | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAEP | c.422-5C>A | Splice Region (SNP) | VAF 41/216 reads (19%) | called by muse, mutect2, varscan2
- PAH | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- PAX1 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 46/246 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH15 | c.2123C>G p.T708R | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PCDH8 | c.1747G>T p.D583Y | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.10945G>T p.D3649Y | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PDZD4 | c.1086G>T p.E362D | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2
- PDZD7 | c.2105C>A p.P702Q | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEG3 | c.1560G>T p.L520F | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX5L | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.386); called by mutect2, varscan2
- PGLYRP2 | c.829C>A p.L277M | Missense Mutation (SNP) | VAF 63/296 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- PHF21B | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PIP4K2A | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- PLEKHB2 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 28/240 reads (12%) | PolyPhen possibly damaging (0.908); called by muse, varscan2
- PLEKHG3 | c.1434C>G p.D478E (on ENST00000394691; = p.D534E on NM_001308147.2) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PLXNA4 | c.4753G>A p.A1585T | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- POLR3GL | c.42G>T p.Q14H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- POSTN | c.2493G>T p.R831S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- POTEG | c.686G>C p.G229A | Missense Mutation (SNP) | VAF 67/557 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- POTEJ | c.2350C>A p.Q784K | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.307); called by muse, mutect2, varscan2
- PPP1R17 | c.343A>T p.R115W | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R26 | c.695A>T p.Q232L | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PRAMEF11 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 14/620 reads (2%) | SIFT tolerated (0.09); PolyPhen benign (0.158); called by muse, mutect2
- PRAMEF20 | c.961C>T p.Q321* | Nonsense Mutation (SNP) | VAF 20/635 reads (3%) | called by muse, mutect2
- PRDM7 | c.1045C>A p.P349T | Missense Mutation (SNP) | VAF 60/654 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2
- PRKAR1B | c.31G>T p.E11* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- PRKCG | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 145/440 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRMT8 | c.1048A>G p.R350G | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PRPH | c.601C>A p.R201S | Missense Mutation (SNP) | VAF 62/330 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- PTPRM | c.3933G>T p.Q1311H | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRQ | c.2473C>A p.P825T (on ENST00000616559; = p.P783T on NM_001145026.2) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRT | c.3309G>T p.M1103I | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRT | c.2074A>T p.N692Y | Missense Mutation (SNP) | VAF 13/305 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PWWP2B | c.1508G>T p.W503L | Missense Mutation (SNP) | VAF 15/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- QRSL1 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- R3HDML | c.283A>T p.R95W | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- RAPGEF5 | c.529A>G p.R177G (on ENST00000401957 / NM_001367602.2; = p.R480G on NM_012294.5) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RASA1 | c.1774C>G p.Q592E | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- RBL2 | c.2711_2720del p.K904Sfs*25 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | called by pindel, varscan2
- RECQL | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.871); called by muse, mutect2
- RNASE13 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ROBO2 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 21/309 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RPS4Y2 | c.111G>T p.K37N | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- RTL3 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- RUBCN | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 60/317 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- RUNX3 | c.580T>C p.F194L | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- RYR1 | c.10105del p.A3369Qfs*56 | Frame Shift Del (DEL) | VAF 109/419 reads (26%) | called by mutect2, pindel, varscan2
- SBK2 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 62/499 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCYL1 | c.2009del p.G670Afs*3 | Frame Shift Del (DEL) | VAF 27/106 reads (25%) | called by mutect2, pindel, varscan2
- SDR42E1 | c.1012G>C p.A338P | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SECISBP2L | c.1282A>T p.N428Y (on ENST00000559471 / NM_001193489.2; = p.N383Y on NM_014701.4) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); called by muse, varscan2
- SEMA3E | c.1280C>T p.T427I | Missense Mutation (SNP) | VAF 47/563 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.988); called by muse, mutect2
- SERPINA4 | c.1001C>A p.P334H | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- SF3B3 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SH2D1A | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 171/334 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHANK2 | c.4385G>T p.S1462I | Missense Mutation (SNP) | VAF 98/663 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHANK2 | c.3586G>T p.A1196S | Missense Mutation (SNP) | VAF 63/382 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SHOC2 | c.1058A>T p.Q353L | Missense Mutation (SNP) | VAF 36/261 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIGLEC9 | c.517G>T p.G173W | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC12A7 | c.1668G>T p.W556C | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- SLC17A1 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLC17A2 | c.1216G>T p.A406S (on ENST00000265425; = p.M356I on NM_005835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.96); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SLC22A7 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2
- SLC27A6 | c.1601C>A p.T534K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC2A7 | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC39A14 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SLC6A4 | c.83A>C p.Q28P | Missense Mutation (SNP) | VAF 74/453 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SLC6A5 | c.99G>T p.R33S | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A7 | c.1377C>A p.H459Q | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- SLFN14 | c.1279C>A p.L427M | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SMARCA5 | c.1895T>G p.I632S | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- SNAP91 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- SNX19 | c.1412G>T p.G471V | Missense Mutation (SNP) | VAF 52/156 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.034); called by mutect2, varscan2
- SORCS1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOX5 | c.278A>T p.D93V | Missense Mutation (SNP) | VAF 56/251 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SPATA31A3 | c.3132C>A p.H1044Q | Missense Mutation (SNP) | VAF 58/650 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); called by muse, varscan2
- SPATA31D1 | c.3614dup p.L1205Ffs*12 | Frame Shift Ins (INS) | VAF 19/123 reads (15%) | called by mutect2, pindel, varscan2
- SPNS1 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SPPL2C | c.2000A>T p.H667L | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, mutect2
- SPTA1 | c.2163G>T p.E721D | Missense Mutation (SNP) | VAF 88/423 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- ST18 | c.1293G>A p.R431= | Splice Region (SNP) | VAF 57/216 reads (26%) | called by muse, mutect2, varscan2
- STON1 | c.1049A>T p.E350V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- STRIP2 | c.802A>T p.K268* | Nonsense Mutation (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- SWT1 | c.166-17_166-8delinsAAATGATAGACTTTTTTTTTAA p.X56_splice | Splice Site (INS) | VAF 3/33 reads (9%) | called by pindel, varscan2*
- SYNE2 | c.4743A>T p.K1581N | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- SYNRG | c.824-7C>A | Splice Region (SNP) | VAF 13/207 reads (6%) | called by muse, mutect2
- SYT9 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- SYTL5 | c.1652T>G p.L551* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | called by muse, mutect2, varscan2
- TAF1L | c.3060A>T p.K1020N | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- TBC1D23 | c.1930A>G p.I644V (on ENST00000394144 / NM_001199198.3; = p.I629V on NM_018309.5) | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TBCCD1 | c.1236G>T p.Q412H | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2
- TCP11L1 | c.904G>T p.V302F | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.444); called by muse, mutect2
- TDRD1 | c.3008-1G>T p.X1003_splice | Splice Site (SNP) | VAF 20/190 reads (11%) | called by muse, mutect2
- TDRD1 | c.3008G>T p.S1003I | Missense Mutation (SNP) | VAF 20/190 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2
- TMEM199 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM245 | c.930G>T p.R310S | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); called by mutect2, varscan2
- TRAV30 | c.237del p.D79Efs*? | Frame Shift Del (DEL) | VAF 44/174 reads (25%) | called by mutect2, pindel, varscan2
- TRBV19 | c.311del p.P104Rfs*11 | Frame Shift Del (DEL) | VAF 50/133 reads (38%) | called by mutect2, pindel, varscan2
- TROAP | c.1378G>T p.G460C | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- TRPC3 | c.779A>T p.E260V (on ENST00000379645 / NM_001366479.2; = p.E187V on NM_003305.2) | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.314); called by muse, mutect2
- TRPC5 | c.1393C>A p.P465T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TRPV6 | c.470-2A>G p.X157_splice | Splice Site (SNP) | VAF 21/112 reads (19%) | called by muse, mutect2, varscan2
- TTC22 | c.624-2A>T p.X208_splice | Splice Site (SNP) | VAF 25/160 reads (16%) | called by muse, mutect2, varscan2
- TTC7B | c.1699G>T p.D567Y | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTLL2 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- TTLL9 | c.13A>T p.R5W | Missense Mutation (SNP) | VAF 15/244 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); called by muse, mutect2
- TTYH3 | c.1272G>T p.E424D | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UGT2A1 | c.644C>A p.S215Y | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UNC5A | c.2148C>A p.D716E | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UNCX | c.1145C>A p.P382H | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- UNKL | c.922T>C p.F308L | Missense Mutation (SNP) | VAF 40/175 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UPRT | c.95del p.G32Afs*3 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- USH2A | c.5573-1G>T p.X1858_splice | Splice Site (SNP) | VAF 24/292 reads (8%) | called by muse, mutect2
- UTP3 | c.1199A>G p.Q400R | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2
- VCAN | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- WDR97 | c.1827C>A p.N609K | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT5A | c.963G>C p.Q321H | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- WTAP | c.1051C>T p.H351Y | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2
- ZIC5 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- ZNF16 | c.1475G>C p.S492T | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZNF333 | c.1616G>A p.C539Y | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF423 | c.992A>G p.H331R (on ENST00000563137 / NM_001379286.1; = p.H323R on NM_015069.4) | Missense Mutation (SNP) | VAF 85/535 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZNF442 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 22/113 reads (19%) | called by muse, mutect2, varscan2
- ZNF492 | c.1528T>A p.C510S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- ZNF560 | c.1790A>T p.E597V | Missense Mutation (SNP) | VAF 52/285 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ZNF716 | c.519T>A p.N173K | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ZNF729 | c.1060G>A p.G354S | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF804B | c.3869C>G p.A1290G | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF85 | c.467A>T p.H156L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZPBP2 | c.152C>A p.P51Q (on ENST00000348931 / NM_199321.3; = p.P29Q on NM_198844.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ABCA4 | c.2697C>T p.P899= | Silent (SNP) | VAF 28/352 reads (8%) | called by muse, mutect2
- AC100868.1 | c.1842C>A p.T614= | Silent (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.189G>T p.A63= | Silent (SNP) | VAF 33/251 reads (13%) | called by muse, mutect2, varscan2
- AIFM3 | c.855C>A p.G285= | Silent (SNP) | VAF 14/264 reads (5%) | called by muse, mutect2
- ALMS1 | c.8928A>T p.V2976= | Silent (SNP) | VAF 56/300 reads (19%) | called by muse, mutect2, varscan2
- ALPK2 | c.5200A>C p.R1734= | Silent (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- AOAH | c.477T>C p.I159= | Silent (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- APOB | c.11973G>A p.Q3991= | Silent (SNP) | VAF 54/325 reads (17%) | called by muse, mutect2, varscan2
- ARMCX2 | c.60C>T p.A20= | Silent (SNP) | VAF 59/115 reads (51%) | called by muse, mutect2, varscan2
- ATG2A | c.1491G>C p.L497= | Silent (SNP) | VAF 54/323 reads (17%) | called by muse, mutect2, varscan2
- BEST1 | c.585G>A p.A195= | Silent (SNP) | VAF 178/605 reads (29%) | catalogued as rs776011957, COSV57121403; called by muse, mutect2, varscan2
- C12orf42 | c.957C>A p.S319= | Silent (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- CALCRL | c.798T>A p.P266= | Silent (SNP) | VAF 12/128 reads (9%) | called by muse, mutect2
- CASP9 | c.39G>T p.R13= | Silent (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- CD6 | c.1611C>A p.I537= | Silent (SNP) | VAF 74/241 reads (31%) | catalogued as rs769846490; called by muse, mutect2, varscan2
- CD93 | c.114G>T p.T38= | Silent (SNP) | VAF 27/264 reads (10%) | catalogued as rs754159699; called by muse, mutect2, varscan2
- CDC34 | c.549G>T p.V183= | Silent (SNP) | VAF 38/200 reads (19%) | called by muse, mutect2, varscan2
- CDCA5 | c.594C>G p.P198= | Silent (SNP) | VAF 62/322 reads (19%) | called by muse, mutect2, varscan2
- CDH20 | c.2232C>G p.S744= | Silent (SNP) | VAF 73/274 reads (27%) | catalogued as COSV53018293; called by muse, mutect2, varscan2
- CDH4 | c.1920C>A p.V640= | Silent (SNP) | VAF 99/568 reads (17%) | called by muse, mutect2, varscan2
- CEP128 | c.2619A>G p.K873= | Silent (SNP) | VAF 63/241 reads (26%) | called by muse, mutect2, varscan2
- CHRNB2 | c.1089G>T p.L363= | Silent (SNP) | VAF 145/467 reads (31%) | called by muse, mutect2, varscan2
- CLCNKA | c.510G>T p.V170= | Silent (SNP) | VAF 136/697 reads (20%) | called by muse, mutect2, varscan2
- CNTNAP5 | c.2277C>A p.V759= | Silent (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- COL12A1 | c.1692G>T p.L564= | Silent (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- COL18A1 | c.432C>A p.V144= | Silent (SNP) | VAF 49/289 reads (17%) | called by muse, mutect2, varscan2
- COL22A1 | c.216C>G p.P72= | Silent (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- CRAMP1 | c.3228C>T p.L1076= | Silent (SNP) | VAF 65/368 reads (18%) | catalogued as rs369235627; called by muse, mutect2, varscan2
- CTNND2 | c.591T>A p.A197= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as rs1410267058; called by muse, mutect2
- CWF19L2 | c.1566A>C p.A522= | Silent (SNP) | VAF 18/110 reads (16%) | called by muse, mutect2, varscan2
- DACH1 | c.636C>A p.P212= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, varscan2
- DACH1 | c.546C>A p.T182= | Silent (SNP) | VAF 18/113 reads (16%) | called by muse, varscan2
- DHX58 | c.1716G>T p.V572= | Silent (SNP) | VAF 38/216 reads (18%) | called by muse, mutect2, varscan2
- DLX3 | c.441C>A p.R147= | Silent (SNP) | VAF 62/261 reads (24%) | catalogued as COSV101460508; called by muse, mutect2, varscan2
- DMP1 | c.1440G>A p.Q480= | Silent (SNP) | VAF 115/450 reads (26%) | catalogued as rs949379753; called by muse, mutect2, varscan2
- DNAH10 | c.3093A>G p.E1031= (on ENST00000409039; = p.E970= on NM_207437.3) | Silent (SNP) | VAF 12/186 reads (6%) | catalogued as rs1565936588; called by muse, mutect2
- DNM1 | c.225T>C p.N75= | Silent (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- ELAPOR2 | c.2610G>A p.E870= (on ENST00000450689 / NM_001142749.3; = p.E703= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/204 reads (26%) | catalogued as COSV51887003; called by muse, mutect2, varscan2
- ELP3 | c.708G>A p.L236= | Silent (SNP) | VAF 40/276 reads (14%) | called by muse, mutect2, varscan2
- EN2 | c.567C>A p.G189= | Silent (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2
- EPHA10 | c.2433A>T p.L811= | Silent (SNP) | VAF 52/233 reads (22%) | called by muse, mutect2, varscan2
- ESRRG | c.402C>A p.I134= | Silent (SNP) | VAF 48/218 reads (22%) | catalogued as COSV63173874; called by muse, mutect2, varscan2
- EXD2 | c.666C>T p.S222= (on ENST00000312994 / NM_001193362.1; = p.S97= on NM_018199.3) | Silent (SNP) | VAF 23/146 reads (16%) | called by muse, mutect2, varscan2
- FAM47C | c.738C>G p.L246= | Silent (SNP) | VAF 108/268 reads (40%) | called by muse, mutect2, varscan2
- FHOD3 | c.2538G>T p.P846= (on ENST00000359247 / NM_001281739.3; = p.P863= on NM_025135.5) | Silent (SNP) | VAF 19/112 reads (17%) | catalogued as COSV57165452, COSV57167855; called by muse, mutect2, varscan2
- FKTN | c.195A>T p.T65= | Silent (SNP) | VAF 12/135 reads (9%) | called by muse, mutect2
- FLG | c.9951C>T p.G3317= | Silent (SNP) | VAF 89/559 reads (16%) | called by muse, mutect2, varscan2
- FREM3 | c.843C>A p.S281= | Silent (SNP) | VAF 10/147 reads (7%) | catalogued as COSV61681203; called by muse, mutect2
- GAL3ST3 | c.180C>A p.R60= | Silent (SNP) | VAF 28/133 reads (21%) | called by muse, mutect2, varscan2
- GMEB1 | c.1380A>G p.P460= | Silent (SNP) | VAF 35/283 reads (12%) | called by muse, mutect2, varscan2
- GPR149 | c.735G>T p.A245= | Silent (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- GRAMD1A | c.1146G>T p.R382= | Silent (SNP) | VAF 53/182 reads (29%) | catalogued as rs1180426138, COSV58767899; called by muse, mutect2, varscan2
- GTF2H4 | c.1224G>A p.L408= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2
- GTSE1 | c.45A>C p.A15= | Silent (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- H2AW | c.381C>A p.A127= | Silent (SNP) | VAF 61/244 reads (25%) | called by muse, mutect2, varscan2
- HHIPL1 | c.1323G>A p.A441= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- IFI27L1 | c.81G>T p.V27= | Silent (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- IGHM | c.1062G>T p.T354= | Silent (SNP) | VAF 92/513 reads (18%) | called by muse, mutect2, varscan2
- ITGBL1 | c.903C>T p.C301= | Silent (SNP) | VAF 8/172 reads (5%) | called by muse, mutect2
- IZUMO2 | c.336C>T p.T112= | Silent (SNP) | VAF 36/121 reads (30%) | called by muse, mutect2, varscan2
- JAKMIP1 | c.798C>A p.P266= | Silent (SNP) | VAF 68/223 reads (30%) | catalogued as COSV51521483; called by muse, mutect2, varscan2
- KCNC2 | c.210G>T p.L70= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1278047836; called by muse, mutect2, varscan2
- KIF1A | c.2199C>A p.L733= | Silent (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- KIF25 | c.618A>G p.L206= | Silent (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- KRT17 | c.51C>A p.S17= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- LANCL2 | c.552G>T p.S184= | Silent (SNP) | VAF 42/192 reads (22%) | called by muse, mutect2, varscan2
- LCT | c.4383C>A p.T1461= | Silent (SNP) | VAF 42/228 reads (18%) | called by muse, mutect2, varscan2
- LRRC32 | c.1698C>A p.L566= | Silent (SNP) | VAF 43/358 reads (12%) | called by muse, mutect2, varscan2
- LRRC7 | c.3915T>A p.P1305= (on ENST00000651989 / NM_001370785.2; = p.P1272= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 6/60 reads (10%) | called by mutect2, varscan2
- LRRK2 | c.5844G>A p.E1948= | Silent (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- MAGEB2 | c.348G>T p.G116= | Silent (SNP) | VAF 53/162 reads (33%) | called by muse, mutect2, varscan2
- MKLN1 | c.24T>C p.A8= | Silent (SNP) | VAF 70/211 reads (33%) | called by muse, mutect2, varscan2
- MUC16 | c.23250C>T p.S7750= | Silent (SNP) | VAF 49/313 reads (16%) | called by muse, mutect2, varscan2
- MYT1L | c.654G>T p.R218= | Silent (SNP) | VAF 73/416 reads (18%) | catalogued as COSV101219764, COSV67733934; called by muse, mutect2, varscan2
- NAV3 | c.604C>A p.R202= | Silent (SNP) | VAF 20/212 reads (9%) | catalogued as COSV57080262, COSV57106346, COSV99887406; called by muse, mutect2
- NEURL2 | c.321G>T p.L107= | Silent (SNP) | VAF 50/248 reads (20%) | called by muse, mutect2, varscan2
- NLRP12 | c.2637T>G p.T879= | Silent (SNP) | VAF 187/609 reads (31%) | catalogued as rs1459561508; called by mutect2, varscan2
- NOG | c.261G>T p.R87= | Silent (SNP) | VAF 48/195 reads (25%) | catalogued as rs1443783507; called by muse, mutect2, varscan2
- NUGGC | c.2031C>A p.I677= | Silent (SNP) | VAF 30/177 reads (17%) | called by muse, mutect2, varscan2
- OR10H2 | c.444C>A p.S148= | Silent (SNP) | VAF 20/81 reads (25%) | catalogued as COSV59946382; called by muse, mutect2, varscan2
- OR5F1 | c.295C>T p.L99= | Silent (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- OR9G1 | c.372C>A p.A124= | Silent (SNP) | VAF 41/272 reads (15%) | catalogued as COSV56450363; called by muse, mutect2, varscan2
- PAPPA | c.2601C>A p.A867= | Silent (SNP) | VAF 38/206 reads (18%) | called by muse, mutect2, varscan2
- PCARE | c.2988C>A p.P996= | Silent (SNP) | VAF 28/148 reads (19%) | called by muse, varscan2
- PCDH15 | c.4083C>A p.T1361= | Silent (SNP) | VAF 19/327 reads (6%) | called by muse, mutect2
- PCDHB14 | c.1500C>G p.L500= | Silent (SNP) | VAF 118/508 reads (23%) | catalogued as rs142260227, COSV53389045; called by muse, mutect2, varscan2
- PIGG | c.2595C>T p.T865= (on ENST00000453061 / NM_001127178.3; = p.T857= on NM_017733.4) | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as COSV56318455; called by muse, mutect2
- PLCG2 | c.2958C>T p.Y986= | Silent (SNP) | VAF 104/463 reads (22%) | catalogued as rs1301281356; called by muse, mutect2, varscan2
- PLEKHA7 | c.3093C>T p.T1031= | Silent (SNP) | VAF 12/203 reads (6%) | catalogued as rs1230570866; called by muse, mutect2
- PLEKHG5 | c.1875G>A p.E625= (on ENST00000400915 / NM_001042663.3; = p.E588= on NM_020631.6) | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as COSV100556243; called by muse, mutect2, varscan2
- PLOD2 | c.270G>T p.V90= | Silent (SNP) | VAF 66/336 reads (20%) | called by muse, mutect2, varscan2
- PNPLA5 | c.381C>A p.R127= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2, varscan2
- PPP1CA | c.195A>T p.I65= | Silent (SNP) | VAF 59/222 reads (27%) | called by muse, mutect2, varscan2
- PTGDR | c.525G>T p.V175= | Silent (SNP) | VAF 107/427 reads (25%) | called by muse, mutect2, varscan2
- PTGIR | c.396G>T p.G132= | Silent (SNP) | VAF 45/162 reads (28%) | called by muse, mutect2, varscan2
- PTPRD | c.312G>A p.V104= | Silent (SNP) | VAF 23/103 reads (22%) | called by muse, mutect2, varscan2
- RAB3GAP2 | c.3489C>T p.S1163= | Silent (SNP) | VAF 23/417 reads (6%) | called by muse, mutect2
- RAB6B | c.369G>T p.L123= | Silent (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- RGS20 | c.582C>A p.A194= (on ENST00000297313 / NM_170587.4; = p.A47= on NM_003702.4) | Silent (SNP) | VAF 23/120 reads (19%) | catalogued as rs772342280; called by muse, mutect2, varscan2
- RGS7 | c.1404A>G p.A468= | Silent (SNP) | VAF 18/354 reads (5%) | called by muse, mutect2
- SDK1 | c.1521C>A p.P507= | Silent (SNP) | VAF 28/211 reads (13%) | called by muse, mutect2, varscan2
- SEC14L1 | c.696G>T p.V232= | Silent (SNP) | VAF 40/186 reads (22%) | called by muse, varscan2
- SEZ6L | c.1245C>A p.A415= | Silent (SNP) | VAF 6/65 reads (9%) | catalogued as COSV50681347; called by muse, varscan2
- SLC26A4 | c.582G>T p.L194= | Silent (SNP) | VAF 54/361 reads (15%) | called by muse, mutect2, varscan2
- SLC29A3 | c.1089G>T p.R363= | Silent (SNP) | VAF 33/262 reads (13%) | catalogued as rs140466083; called by muse, mutect2, varscan2
- SLC2A10 | c.273C>A p.T91= | Silent (SNP) | VAF 18/452 reads (4%) | called by muse, mutect2
- SLC5A4 | c.39C>A p.T13= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- SLFN14 | c.1953G>T p.G651= | Silent (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- SNX20 | c.33C>G p.G11= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- SRPK2 | c.984A>T p.T328= | Silent (SNP) | VAF 53/276 reads (19%) | called by muse, mutect2, varscan2
- TECRL | c.465G>T p.L155= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV67085943; called by muse, mutect2, varscan2
- TEX52 | c.858C>A p.S286= | Silent (SNP) | VAF 24/113 reads (21%) | called by muse, mutect2, varscan2
- TIMP3 | c.567C>A p.G189= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as rs753287182; called by muse, mutect2, varscan2
- TMEM132C | c.726C>A p.A242= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV70663533; called by muse, mutect2, varscan2
- TMEM270 | c.366G>T p.L122= | Silent (SNP) | VAF 39/311 reads (13%) | called by muse, mutect2, varscan2
- TMEM51 | c.537G>T p.V179= | Silent (SNP) | VAF 47/236 reads (20%) | called by muse, mutect2, varscan2
- TNR | c.783C>T p.C261= | Silent (SNP) | VAF 58/363 reads (16%) | called by muse, mutect2, varscan2
- TTLL1 | c.948C>T p.I316= | Silent (SNP) | VAF 29/229 reads (13%) | catalogued as rs756215079, COSV56738208; called by muse, mutect2, varscan2
- TTLL8 | c.1224C>A p.I408= | Silent (SNP) | VAF 41/366 reads (11%) | called by muse, mutect2, varscan2
- UNC79 | c.5688G>C p.P1896= (on ENST00000393151 / NM_001346218.2; = p.P1719= on NM_020818.5) | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV56382814; called by muse, mutect2
- USP9Y | c.1509G>T p.V503= | Silent (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- WDFY4 | c.1341C>T p.H447= | Silent (SNP) | VAF 36/226 reads (16%) | called by muse, mutect2, varscan2
- XKR4 | c.1071C>A p.L357= | Silent (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- ZAN | c.1332C>A p.A444= | Silent (SNP) | VAF 33/320 reads (10%) | called by muse, mutect2, varscan2
- ZNF557 | c.843G>T p.G281= (on ENST00000414706 / NM_001044388.2; = p.G288= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/193 reads (21%) | called by muse, mutect2, varscan2
- AC009039.2 | chr16:52084374 C>A | 5'Flank (SNP) | VAF 73/375 reads (19%) | catalogued as rs1037332458; called by muse, mutect2, varscan2
- AGAP3 | c.223+22G>T | Intron (SNP) | VAF 25/214 reads (12%) | called by muse, mutect2, varscan2
- AKAP1 | c.1714+841G>T | Intron (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2
- AL137230.1 | n.502+1805G>C | Intron (SNP) | VAF 14/216 reads (6%) | catalogued as rs1387154721; called by muse, mutect2
- AP002008.2 | n.1646G>A | RNA (SNP) | VAF 45/194 reads (23%) | called by muse, mutect2, varscan2
- AR | c.1769-5275A>G | Intron (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2
- BBIP1 | c.38-6099A>T | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- CFAP46 | c.3219+64G>T | Intron (SNP) | VAF 28/232 reads (12%) | catalogued as rs1318324616; called by muse, mutect2, varscan2
- CFAP74 | c.2176+400G>A | Intron (SNP) | VAF 17/214 reads (8%) | catalogued as rs1472191669; called by muse, mutect2
- CGREF1 | chr2:27099613 C>A | 3'Flank (SNP) | VAF 140/626 reads (22%) | catalogued as rs755019513; called by muse, varscan2
- CHIT1 | c.1030-216C>A | Intron (SNP) | VAF 38/177 reads (21%) | called by muse, mutect2, varscan2
- CMPK2 | c.*38G>C | 3'UTR (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- COX6B2 | c.*65G>A | 3'UTR (SNP) | VAF 30/63 reads (48%) | catalogued as rs1274401973; called by muse, mutect2, varscan2
- CTNNBL1 | c.-72G>T | 5'UTR (SNP) | VAF 20/109 reads (18%) | called by muse, mutect2, varscan2
- DCUN1D2 | c.3+233G>T | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- DDHD1 | c.319+652G>T | Intron (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- DLX6 | c.437-26C>A | Intron (SNP) | VAF 35/324 reads (11%) | called by muse, mutect2, varscan2
- DOK7 | c.-11C>A | 5'UTR (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2, varscan2
- DVL3 | c.161+585G>T | Intron (SNP) | VAF 69/386 reads (18%) | called by muse, mutect2, varscan2
- ECE2 | c.401-50G>T | Intron (SNP) | VAF 14/354 reads (4%) | called by muse, mutect2
- EPM2A | c.*1702A>T | 3'UTR (SNP) | VAF 62/324 reads (19%) | called by muse, mutect2, varscan2
- FAM220BP | n.639G>T | RNA (SNP) | VAF 75/322 reads (23%) | called by muse, mutect2, varscan2
- FCN1 | c.*397A>T | 3'UTR (SNP) | VAF 58/281 reads (21%) | called by muse, mutect2, varscan2
- FLNB | c.7622-24G>T | Intron (SNP) | VAF 17/209 reads (8%) | called by muse, mutect2
- FMO6P | n.1202C>A | RNA (SNP) | VAF 26/214 reads (12%) | called by muse, mutect2
- FOXP2 | c.1094+32G>T | Intron (SNP) | VAF 27/194 reads (14%) | catalogued as COSV100647433; called by muse, mutect2, varscan2
- FOXP2 | c.*3274A>T | 3'UTR (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- FUNDC2P2 | n.579G>T | RNA (SNP) | VAF 78/320 reads (24%) | catalogued as rs745487843; called by muse, mutect2, varscan2
- GCNT2 | chr6:10634359 A>T | 3'Flank (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- GLYATL1 | n.126G>A | RNA (SNP) | VAF 30/384 reads (8%) | called by muse, mutect2
- GVINP1 | n.7216C>T | RNA (SNP) | VAF 34/153 reads (22%) | called by muse, mutect2, varscan2
- IGFN1 | c.1924+148C>A | Intron (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- JAG2 | c.2394-34G>T | Intron (SNP) | VAF 85/504 reads (17%) | catalogued as rs1003015930; called by mutect2, varscan2
- KLF6 | c.*2082_*2083del | 3'UTR (DEL) | VAF 40/280 reads (14%) | called by pindel, varscan2
- KNOP1P1 | n.310G>A | RNA (SNP) | VAF 16/66 reads (24%) | catalogued as rs1167429857; called by muse, mutect2, varscan2
- LAMA1 | c.8094+190C>A | Intron (SNP) | VAF 39/174 reads (22%) | catalogued as COSV101055211; called by muse, mutect2, varscan2
- LINC01619 | n.1309G>C | RNA (SNP) | VAF 20/328 reads (6%) | catalogued as rs1173515569; called by muse, mutect2
- LY6K | c.-75_-74del | 5'UTR (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- MGAM | c.4619-13765C>T | Intron (SNP) | VAF 56/239 reads (23%) | catalogued as rs750282712, COSV72074749; called by muse, mutect2, varscan2
- MGAM | c.4619-13764C>A | Intron (SNP) | VAF 55/241 reads (23%) | called by muse, mutect2, varscan2
- MPV17 | c.279+21G>C | Intron (SNP) | VAF 60/652 reads (9%) | called by muse, mutect2
- MYLK | c.773+49G>T | Intron (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
- MYLK3 | c.2115-27A>T | Intron (SNP) | VAF 20/295 reads (7%) | called by muse, mutect2
- Metazoa_SRP | chr17:18610243 G>T | 5'Flank (SNP) | VAF 28/348 reads (8%) | called by muse, mutect2
- NAA60 | c.*223C>T | 3'UTR (SNP) | VAF 28/107 reads (26%) | catalogued as rs1567405348; called by muse, mutect2, varscan2
- NALCN | c.2193-5284C>A | Intron (SNP) | VAF 16/159 reads (10%) | called by muse, mutect2, varscan2
- NDRG4 | c.-77C>A | 5'UTR (SNP) | VAF 16/213 reads (8%) | called by muse, mutect2
- NMNAT3 | c.110-20300T>A | Intron (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1553A>G | RNA (SNP) | VAF 45/298 reads (15%) | catalogued as rs763794377; called by muse, mutect2, varscan2
- NOC2LP2 | n.952C>A | RNA (SNP) | VAF 38/226 reads (17%) | called by muse, varscan2
- NPIPB10P | n.1283C>T | RNA (SNP) | VAF 60/456 reads (13%) | catalogued as rs1382509147; called by muse, varscan2
- NTRK3 | c.1586-38557C>A | Intron (SNP) | VAF 54/228 reads (24%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2300C>T | Intron (SNP) | VAF 68/688 reads (10%) | catalogued as rs775075503; called by muse, mutect2
- OR2C3 | c.*4527C>A | 3'UTR (SNP) | VAF 11/248 reads (4%) | called by muse, mutect2
- PDE6G | c.*181C>G | 3'UTR (SNP) | VAF 65/278 reads (23%) | called by muse, mutect2, varscan2
- PDZRN3 | c.919-70145A>G | Intron (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- PEX19 | c.*57G>C | 3'UTR (SNP) | VAF 32/517 reads (6%) | called by muse, mutect2
- PLA2G6 | c.210-2898dup | Intron (INS) | VAF 18/147 reads (12%) | called by mutect2, varscan2
- PLA2G6 | c.210-2899delinsTT | Intron (INS) | VAF 18/167 reads (11%) | catalogued as COSV59271338; called by mutect2*, pindel, varscan2*
- PPP1R12B | c.847-15C>T | Intron (SNP) | VAF 21/120 reads (18%) | called by muse, mutect2, varscan2
- PSMA2 | c.41+975G>C | Intron (SNP) | VAF 10/140 reads (7%) | called by muse, mutect2
- RBL2 | c.2704-12A>C | Intron (SNP) | VAF 34/150 reads (23%) | called by muse, varscan2
- RNA5-8SP2 | chr16:34159141 G>T | 5'Flank (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- RPL37A | c.133-100C>G | Intron (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- RPS12 | c.235-83C>G | Intron (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- RSPO1 | c.-6G>T | 5'UTR (SNP) | VAF 27/439 reads (6%) | called by muse, mutect2
- SLC22A25 | c.1071-1779C>A | Intron (SNP) | VAF 16/50 reads (32%) | called by muse, mutect2, varscan2
- SLC4A10 | c.*5T>C | 3'UTR (SNP) | VAF 15/73 reads (21%) | catalogued as rs954475198; called by muse, mutect2, varscan2
- SMPDL3B | c.276-26C>T | Intron (SNP) | VAF 20/492 reads (4%) | called by muse, mutect2
- SOX12 | c.*7C>T | 3'UTR (SNP) | VAF 14/230 reads (6%) | catalogued as COSV100705309; called by muse, mutect2
- SPATA31D5P | n.963G>C | RNA (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- TMEM135 | c.*3697G>C | 3'UTR (SNP) | VAF 47/163 reads (29%) | called by muse, mutect2, varscan2
- TRMT9B | chr8:13031358 C>A | 3'Flank (SNP) | VAF 42/242 reads (17%) | called by muse, mutect2, varscan2
- UBTFL2 | n.798G>T | RNA (SNP) | VAF 116/512 reads (23%) | called by muse, mutect2, varscan2
- XIST | n.7376C>A | RNA (SNP) | VAF 29/176 reads (16%) | called by muse, mutect2, varscan2
- ZNF846 | c.-19G>T | 5'UTR (SNP) | VAF 45/241 reads (19%) | called by muse, mutect2, varscan2
